Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A3GK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A3GK-01A (Primary Tumor).

[page 1 of 4]
11/29/11

Surgical Pathology Report

Final

10D-0-3
adenocarcinoma, endocervical type 8384/3
Site: cervix, NOS C53.9 11/29/11

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name:	[REDACTED]	Service:	Gynecology	Accession #:	
Address:	[REDACTED]	Location:	OTHER	Taken:	
Gender:	F	MRN:	[REDACTED]	Received:	
DOB:	[REDACTED]	Hospital #:	[REDACTED]	Accessioned:	
		Patient Type:	[REDACTED]	Reported:	

Physician(s):

DIAGNOSIS:

- A. CECAL BIOPSY
- NO EVIDENCE OF MALIGNANCY
- B. LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION
- NINE LYMPH NODES, NO EVIDENCE OF MALIGNANCY (0/9)
- C. LYMPH NODE, RIGHT OBTURATOR, EXCISION
- THREE LYMPH NODES, NO EVIDENCE OF MALIGNANCY (0/3)
- D. LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION
- ONE LYMPH NODE, NO EVIDENCE OF MALIGNANCY (0/1)
- E. LYMPH NODE, LEFT OBTURATOR, EXCISION
- NINE LYMPH NODES, NO EVIDENCE OF MALIGNANCY (0/9)
- F. UTERUS, CERVIX, BILATERAL TUBES AND OVARIES, RADICAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY

CERVIX:

- INVASIVE ENDOCERVICAL ADENOCARCINOMA, CONVENTIONAL TYPE (POORLY DIFFERENTIATED)
- THE DEPTH OF TUMOR INVASION IS ABOUT 3.6 MM (THE THICKNESS OF THE WALL IS 11 mm)
- THE LATERAL EXTENSION OF THE INVASIVE CARCINOMA IS 13 MM
- EXTENSIVE LYMPHOVASCULAR SPACE INVASION PRESENT
- RESECTION MARGIN NEGATIVE FOR TUMOR
- SEE COMMENT AND SYNOPTICS

UTERINE BODY:

- LOWER UTERINE SEGMENT FREE OF TUMOR
- WEAKLY PROLIFERATIVE ENDOMETRIUM
- UNREMARKABLE MYOMETRIUM

OVARY AND FALLOPIAN TUBE, RIGHT AND LEFT

- HISTOLOGICALLY UNREMARKABLE

G. OMENTUM, BIOPSY

- NO EVIDENCE OF MALIGNANCY

[page 2 of 4]
Patient Name: [REDACTED]
DOB: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

"Called to pick 'radical hysterectomy and bilateral salpingo-oophorectomy,' consist of a 88-gram specimen including uterus, cervix, upper vagina, bilateral ovaries and fallopian tubes. The endocervix has a centrally located 2.4 x 2.2 x 0.5 cm exophytic pink mass. Parametria inked. Uterus and cervix opened to show the cervical mass is grossly confined to the cervix. The endometrial cavity is unremarkable. The portion of tumor plus right fallopian tube taken for [REDACTED] Shown to surgeon. Rest for permanents."

Microscopic Description and Comment:

This tumor consists of solid areas admixed with glandular and papillary growth pattern. In some areas the tumor cells are large and pleomorphic, mimic high grade serous carcinoma. Immunostains showed that the tumor cells were diffusely positive for p16 but negative for p53 and PR. Less than 1% tumor cells showed weak ER positivity. Ki-67 proliferation index was about 80% in the tumor cells. In situ hybridization demonstrated high risk HPV in tumor cells. These findings support the diagnosis of a conventional type endocervical adenocarcinoma.

History:

The patient is a [REDACTED]-year-old woman. Stage 1b1 adenocarcinoma of endocervix. Operative procedure: Radical hysterectomy, bilateral salpingo-oophorectomy, pelvic lymphadenectomy, omental biopsy, cecal biopsy, washing.

Specimen(s) Received:

- A: CECAL BIOPSY
- B: LYMPH NODE, RIGHT EXTERNAL ILIAC
- C: LYMPH NODE, RIGHT OBTURATOR
- D: LYMPH NODE, LEFT EXTERNAL ILIAC
- E: LYMPH NODE, LEFT OBTURATOR
- F: HYSTERECTOMY, BSO
- G: OMENTUM

Gross Description:

The specimens are received in seven formalin-filled containers, each labeled [REDACTED]. The first container is also labeled "cecal biopsy." It holds 0.3 x 0.1 x 0.1 cm pink soft tissue. Entirely submitted in A1. Jar 0.

The second container is also labeled "right external iliac lymph node." It holds 7.5 x 5.0 x 1.5 cm aggregate of yellow soft adipose tissue. Sectioned to show putative lymph nodes. Labeled B1 to B4 - putative lymph nodes. Jar 1.

The third container is also labeled "right obturator lymph node." It holds 5.0 x 3.0 x 1.0 cm fragment of adipose tissue. It holds putative lymph nodes. Labeled C1 to C3 - putative lymph nodes. Jar 1.

The fourth container is also labeled "left external iliac lymph node." It holds 4.5 x 2.0 x 0.5 cm soft yellow adipose tissue containing one lymph node measuring 1.7 x 0.7 x 0.2 cm. Labeled D1 - one lymph node. Jar 1.

[page 3 of 4]
Patient Name: [REDACTED]
DOB: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

The fifth container is also labeled "left obturator lymph node." It holds 5.5 x 2.0 x 0.7 cm adipose tissue fragment containing no grossly visible lymph node. Labeled E1 to E4 - entire specimen, Jar O.

The sixth container is also labeled "radical hysterectomy and bilateral salpingo-oophorectomy." It holds 69 gram uterus measuring 6.5 x 3.5 x 2.7 cm with attached cervix measuring 2.2 x 3.4 x 2.0 cm with attached vaginal cuff measuring 1.3 cm in greater length. Right and left adnexa are attached to the main specimen and measure: right fallopian tube (6 cm in length with fimbriated end); left fallopian tube (5.0 cm in length with fimbriated end); right ovary (3 x 2.0 x 1.7 cm); left ovary (2.7 x 1.7 x 1.7 cm). Opened to show endometrial cavity measuring 4.0 cm in length and 1.7 cm in greatest width. The endometrium measures 0.1 cm in thickness. The myometrium measures 1.0 cm in thickness. There is exophytic tan-pink mass located mostly on anterior ectocervix partially involving posterior ectocervix and extending grossly into endocervical canal. Lesion located 1.5 cm from the edge of the vaginal cuff. Right and left fallopian tubes have paratubal cysts. Section of the right and left ovary show multiple cysts measuring from 0.3 to 1.0 cm in greatest dimension. Labeled F1 - right parametrial margin; F2 - left parametrial margin; F3 - remainder of right parametrium; F4 - remainder of left parametrium; F5 - vaginal cuff margin; F6 to F8 - entire anterior cervix including ectocervix and endocervix and partial lower uterine segment; F9 - anterior lower uterine segment; F10 to F11 - posterior ecto-and-endocervix partially with lower uterine segment and with a lesion; F12 - grossly uninvolved posterior cervix (anterior and posterior cervix are submitted entirely); F13 - posterior lower uterine segment; F14 - anterior endometrium full thickness; F15 - posterior endometrium full thickness; F16 - right fallopian tube and right ovary; F17 - left fallopian tube and left ovary.

The seventh container is also labeled "omental biopsy." It holds 10.0 x 3.0 x 0.5 cm fragment of adipose tissue with no obvious lymph nodes or grossly identifiable lesions. Labeled G1 to G4 - representative section of adipose tissue. Jar 1.

SYNOPTIC REPORTING FORM FOR UTERINE CERVICAL NEOPLASMS

HISTOPATHOLOGIC TYPE
endocervical adenocarcinoma, conventional type

TUMOR SIZE
The maximum depth of the tumor invasion is 3.5 mm
The breadth (maximum horizontal dimension) of the tumor is 13 mm
The total thickness of the cervix is 11 mm

LYMPHATIC INVASION
Lymphatic invasion by tumor is identified and is extensive

HISTOPATHOLOGIC GRADE
The histologic grade is poorly differentiated (G3)

TUMOR INVASION
The tumor does not invade through the entire thickness of the cervix to involve contiguous parametrial tissues.

VAGINAL INVOLVEMENT
The tumor does not involve the vagina

TUMOR METASTASIS
Metastasis of tumor to regional lymph nodes is absent
The total number of metastatically-involved lymph nodes is 0
The total number of lymph nodes examined is 22
Extracapsular extension of metastatic tumor through the lymph node capsule is not applicable; no metastasis seen

PRIMARY TUMOR (T)
Clinically visible lesion 4.0 cm or less in greatest dimension (T1b1)

REGIONAL LYMPH NODES

[page 4 of 4]
Patient Name: [REDACTED]
DOB: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

No regional lymph node metastasis (N0)

DISTANT METASTASIS

Distant metastasis cannot be assessed (MX)

STAGE GROUPING

pT1B1/No/Mx

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Surgical Pathology report is available on-line on [REDACTED]

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Information: Each specimen must be accompanied by a pathology form as provided by the Department of Health.

Information: Each specimen must be accompanied by a pathology form as provided by the Department of Health.

Information: Each specimen must be accompanied by a pathology form as provided by the Department of Health.

Information: Each specimen must be accompanied by a pathology form as provided by the Department of Health.

END OF REPORT

Page 4 of 4

Source: NCI Genomic Data Commons file d4b0fdfe-0f03-4452-9e86-25dd44d2b978 (TCGA-EK-A3GK.FA43F625-0F3A-4CAD-B55D-A00113DEA927.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).